Somatic mutation profile of tumor specimen TCGA-19-A6J4-01A (aliquot TCGA-19-A6J4-01A-11D-A33T-08) from TCGA case TCGA-19-A6J4, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 68.6 years (25,058 days).
Specimen TCGA-19-A6J4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 37bf410f-18e7-44fc-8cfa-b56c6542490b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-19-A6J4-10A (Blood Derived Normal), aliquot TCGA-19-A6J4-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c74b245d-010c-4ce7-8506-0e821c2408f8

The open-access MAF lists 31 somatic variants for this specimen: 22 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 20, Silent 9, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GALNS | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1028668536, CM950525, COSV51939486, COSV99243329; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AMHR2 | c.1510C>T p.R504C | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772294564, CM960062, COSV57685681; called by muse, mutect2, varscan2
- CCER1 | c.241G>A p.V81M | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as rs768934116, COSV62648259; called by muse, mutect2, varscan2
- CCSER1 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1334344518, COSV100394162; called by muse, varscan2
- CD226 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs751925448, COSV99711312; called by muse, mutect2, varscan2
- EIF4G3 | c.2414T>C p.F805S | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99945011; called by muse, mutect2, varscan2
- HMSD | c.118C>T p.R40* | Nonsense Mutation (SNP) | VAF 14/103 reads (14%) | catalogued as rs761923017, COSV68816811; called by muse, mutect2, varscan2
- MACROD2 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs557866799, COSV54026962; called by muse, mutect2, varscan2
- MINPP1 | c.1274C>G p.A425G | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.68); PolyPhen benign (0.194); catalogued as COSV100916776; called by muse, mutect2, varscan2
- MPEG1 | c.1144T>C p.Y382H | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV99915690; called by muse, mutect2, varscan2
- OR2M5 | c.343T>A p.L115M | Missense Mutation (SNP) | VAF 36/295 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100822844; called by muse, mutect2, varscan2
- PTPRK | c.1300G>T p.G434C | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV100951110; called by muse, mutect2
- RASAL3 | c.1579C>A p.Q527K | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.216); catalogued as COSV100640318; called by muse, mutect2, varscan2
- RREB1 | c.3599C>T p.A1200V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs1279358138, COSV58561745; called by muse, mutect2, varscan2
- SERPINB2 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs184826316, COSV55094443; called by mutect2, varscan2
- SPINK2 | c.169T>C p.S57P | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.601); catalogued as COSV99954266; called by muse, mutect2, varscan2
- SPTA1 | c.5431C>T p.R1811* | Nonsense Mutation (SNP) | VAF 14/84 reads (17%) | catalogued as rs770137350, COSV100935229; called by muse, mutect2, varscan2
- ST14 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.084); catalogued as rs1011753975, COSV99598964; called by muse, mutect2, varscan2
- TM7SF2 | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377189788; called by muse, mutect2, varscan2
- TRMT1L | c.302A>G p.N101S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV100834677; called by muse, mutect2, varscan2
- USP43 | c.2441C>G p.P814R | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99556458, COSV99556867; called by muse, mutect2, varscan2
- FLG | c.2284G>A p.V762M | Missense Mutation (SNP) | VAF 120/395 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- CFAP57 | c.378G>A p.T126= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as rs759535133, COSV100994008; called by muse, mutect2, varscan2
- DNAH3 | c.813C>T p.F271= | Silent (SNP) | VAF 9/131 reads (7%) | catalogued as COSV99769049; called by muse, mutect2
- GIGYF2 | c.3267G>A p.R1089= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV65251196; called by muse, mutect2, varscan2
- KRTAP8-1 | c.9C>T p.C3= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as rs377191830; called by muse, mutect2, varscan2
- OTOA | c.660C>T p.Y220= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs139292090; ClinVar: likely benign; called by muse, mutect2, varscan2
- PITPNM1 | c.822G>A p.P274= | Silent (SNP) | VAF 33/116 reads (28%) | catalogued as rs528484490, COSV100711705; called by muse, mutect2, varscan2
- TBL1Y | c.1062C>A p.T354= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV100667308; called by muse, mutect2, varscan2
- TGFB2 | c.61C>T p.L21= | Silent (SNP) | VAF 25/90 reads (28%) | catalogued as rs1263352886, COSV100860326; called by muse, mutect2, varscan2
- ZNF713 | c.303C>G p.T101= (on ENST00000633730 / NM_001366796.2; = p.T114= on NM_182633.3) | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV101448746; called by muse, mutect2, varscan2
